Surgical pathology report (de-identified scan), TCGA case TCGA-IB-A5ST, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-A5ST-01A (Primary Tumor).

[page 1 of 4]
Note: If you do not see "END OF PRINTED REPORT" at the bottom of the report **YOU DO NOT HAVE THE ENTIRE REPORT**. Please try print

CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Order Number

Status Final

Relevant
Information
Location

Copied To Copy to Request, Insufficient Data for

Report Patient Name

Demographics

(for verification purposes)

Date of Birth:

Sex: F

ICD-O-3

Adenocarcinoma, duct NOS
8500/3

Site: Head of pancreas
C25.0

JW 4/2/13

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description
A. Gallbladder at
B. 8A node at
C. Whipple specimen at

Clinical Information
Pancreatic mass
Infectious patient: No
Immunocompromised: No
History of neoplasm: No

Diagnosis

- A. Gallbladder, Cholecystectomy:
- Mild acute and chronic cholecystitis.
- Negative for dysplasia or malignancy.
- Cystic duct lymph node negative for malignancy.
- B. "8A Lymph Node":
- Mineral oil lipogranulomatosis.
- Negative for malignancy.
- C. Head of Pancreas, Whipple's Resection:
- Invasive well to moderate differentiated pancreatic duct

[page 2 of 4]
- adenocarcinoma.
- Margins clear.
- Metastatic carcinoma involving two of sixteen peripancreatic lymph nodes.

Electronically signed by:

Synoptic Report

C: Pancreas (Exocrine), Macroscopic

SPECIMEN:

Head of pancreas

Duodenum

Common bile duct

Gallbladder

PROCEDURE:

Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

TUMOR SIZE:

Greatest dimension: 3.2 cm

Additional dimensions: 2.5 x 2.0 cm

C: Pancreas (Exocrine), Microscopic

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G2: Moderately differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades duodenal wall

Tumor invades peripancreatic soft tissues

MARGINS:

Margins uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 2 mm

Specified margin: Uncinate margin

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

Not known

LYMPH-VASCULAR INVASION:

Not identified

PERINEURAL INVASION:

Present

PRIMARY TUMOR (pT):

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

Number examined: 2

Number involved: 16

DISTANT METASTASIS (pM):

Not applicable

Gross Description

Received are specimen containers A to C. All requisitions and specimen containers are labelled with the patient's name, The cassettes and AP identifiers are labelled with the Surgical number

A. The specimen is received fresh and is subsequently placed into formalin. The container is designated " Gallbladder" and consists of an unopened gallbladder, measuring 11.0 cm in length x 5.0 x 3.5 cm. The outer peritoneal surface is smooth and unremarkable. The lumen contains green mucoid bile as well as an oval, slightly lobulated gallstone, measuring 2.7 x 1.6 x 1.5 cm. On fracturing the stone has a typical crystalline appearance of a cholesterol stone. The mucosa shows a focal sessile polypoid

[page 3 of 4]
area, 0.4 cm in greatest dimension, but is otherwise velvety and smooth and the gallbladder wall has a thickness of 0.2 cm. A small cystic duct lymph node, 0.7 cm in greatest dimension is present adjacent to the cystic duct resection margin. Sections are taken as follows:

A1. resection margin with cystic duct lymph node as well as section from fundus

A2. sections of body with small polypoid protrusions

B. Specimen is received in formalin. The container is designated as "8A node" and consists of a old fragment of firm, grey tan tissue, measuring 2.0 x 1.1 x 0.6 cm. Bisected and submitted in toto in one cassette.

C. The specimen is received fresh and is subsequently placed into formalin. The container is designated as "Whipple specimen". This consists of a pancreaticoduodenectomy specimen, the segment of distal stomach and small bowel, measuring 17.0 cm in length. The head of pancreas measures approximately 5.0 x 4.5 x 3.5 cm. The neck of the pancreas is painted blue, the uncinate process margin is painted orange. The mucosa of the duodenum is unremarkable with no tumor. The ampulla of Vater is unremarkable. The common bile duct is opened in the fresh state revealing a branching at the superior edge of the pancreas where the cystic duct joins the common hepatic duct. The common bile duct, measures 3.5 cm in length. The attached portion of cystic duct, measures 2.7 cm and the attached portion of common hepatic duct, measures approximately 1.0 cm. The mucosal surface of the ducts are unremarkable. A coronal section into the head of pancreas reveals a firm tumorish mass occupying much of the head of pancreas, with dimensions of 3.2 x 2.5 x 2.0 cm. The tumor appears to approach close to the inferior and uncinate margins, but small portion of pancreatic tissue superior to the tumor and extending to the pancreatic neck resection margin has a fibrous consistency. The section of soft tissue around the head of pancreas reveals scatter lymph nodes. Sections are taken as follows:

- C1. proximal resection margin common bile duct
- C2. proximal resection margin cystic duct
- C3. pancreatic neck resection margin, en face
- C4-6. sections of ampulla of Vater with underlying tumor
- C7-10. tumor including uncinate margin and posterior soft tissue margin
- C11. possible lymph nodes in a fatty tissue operative curvature
- C12-14. three possible large lymph nodes along superior aspect of head of pancreas
- C15. three lymph nodes in gastroduodenal region
- C16. proximal resection margin/antral mucosa
- C17. gastroduodenal junction
- C18/19. distal resection margin duodenum

Microscopic Description

A. Sections show mild acute and chronic inflammation involving the gallbladder with focal polypoid protrusions in the mucosa bed without any evidence of dysplasia or malignancy. The cystic duct lymph node shows slight granulomatosis and is negative for malignancy.

B. Sections show lymph node tissue with lipogranulomatosis. There is no evidence of malignancy.

C. There is an invasive well to moderately differentiated adenocarcinoma involving much of the head of the pancreas. The carcinoma invades through the muscularis propria in the vicinity of the common bile duct, but does not reach the duodenal mucosa. The common bile duct mucosa is partly effaced by the invasive carcinoma. The tumor shows prominent perineural invasion and extends into peripancreatic adipose tissue. The tumor lies close to the uncinate resection margin, but there is a narrow rim of fatty tissue with a clear margin of approximately 0.2 cm. The posterior retroperitoneal margin is clear as well. The pancreatic neck margin shows prominent fibrosis with loss of pancreatic tissue or

[page 4 of 4]
chronic pancreatitis, possibly related to the development of carcinoma. No calcifications are present. The section from the proximal bile duct and cystic duct margins show mild inflammation and reactive changes, but no sign of dysplasia or malignancy.

The carcinoma invades directly into two peripancreatic lymph nodes regarded as positive for nodal involvement, although distant lymph nodes do not show tumor.

Accession
Number
Encounter
Number
Patient Location

— END OF PRINTED REPORT —

Diagnostic Discrepancy		/
HIS-PA Discrepancy		/
Path Synchronous Primary Noted		/
Case in Circle:		

Source: NCI Genomic Data Commons file 6d3cc428-7236-4317-8a44-b95ae71fc163 (TCGA-IB-A5ST.DB6AF92C-6929-41F6-A40F-4CA1C40F2A30.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).